Somatic mutation profile of tumor specimen C3N-03849-01 (aliquot CPT0237130007) from CPTAC case C3N-03849, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 55.8 years (20,363 days).
Specimen C3N-03849-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d248ce36-64da-4cb4-bb40-ed3eea7e235d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03849-31 (Blood Derived Normal), aliquot CPT0237190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82e983fa-f19e-4810-a0f3-60d2fe4332fd

The open-access MAF lists 156 somatic variants for this specimen: 105 protein-altering or splice-affecting, 36 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 36, Nonsense Mutation 11, Frame Shift Del 8, Intron 5, In Frame Del 4, RNA 4, 5'UTR 3, 3'UTR 2, Frame Shift Ins 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 23/180 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 66/223 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs138774498, COSV104409772; called by muse, mutect2, varscan2
- AXIN2 | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 66/664 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV61056603, COSV61059097; called by muse, mutect2
- CLEC14A | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60564162; called by muse, mutect2, varscan2
- CNPY1 | c.115T>G p.S39A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.729); catalogued as rs1239290330; called by muse, mutect2, varscan2
- CPT1A | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 45/279 reads (16%) | catalogued as COSV55761984; called by muse, mutect2, varscan2
- CTNNA2 | c.1051A>C p.N351H | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs1185995811, COSV63547281; called by muse, mutect2, varscan2
- CUBN | c.9534G>C p.M3178I | Missense Mutation (SNP) | VAF 42/473 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100913752; called by muse, mutect2
- CUX2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs763070804, COSV99919862; called by muse, varscan2
- DIP2A | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs1314351049; called by muse, mutect2, varscan2
- ECM1 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 61/317 reads (19%) | catalogued as COSV60872124; called by muse, mutect2, varscan2
- EEF1G | c.630_631del p.C210* | Nonsense Mutation (DEL) | VAF 13/103 reads (13%) | catalogued as rs1565261606; called by pindel, varscan2
- ERCC6 | c.2487_2489del p.E829del | In Frame Del (DEL) | VAF 43/336 reads (13%) | catalogued as rs886047036; called by pindel, varscan2
- FZD7 | c.1195A>G p.M399V | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs1376413817; called by muse, mutect2, varscan2
- GDF1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.292); catalogued as rs1258108118; called by muse, mutect2, varscan2
- GRAMD1B | c.2159G>A p.G720D | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs772471280, COSV59204124; called by muse, mutect2, varscan2
- IGHV3-49 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1228073060; called by muse, mutect2, varscan2
- LAMTOR5 | c.28G>A p.E10K (on ENST00000602318 / NM_001382293.1; = p.E92K on NM_006402.3) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs962263961; called by muse, varscan2
- MMP19 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | catalogued as rs530702678, COSV59450587; called by muse, mutect2, varscan2
- MOB3C | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs766409369, COSV54719463; called by muse, mutect2, varscan2
- MTCH1 | c.1111C>T p.R371* (on ENST00000373627 / NM_001271641.1; = p.R354* on NM_014341.2) | Nonsense Mutation (SNP) | VAF 37/213 reads (17%) | catalogued as rs1261354210, COSV65321068; called by muse, mutect2, varscan2
- NAT10 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.153); catalogued as rs374680907; called by muse, mutect2
- NEDD9 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373145975; called by muse, mutect2, varscan2
- NSUN3 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV58935089; called by muse, mutect2, varscan2
- NUMA1 | c.6193C>T p.R2065W | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs369599832; called by muse, mutect2
- OR6C3 | c.23_24del p.E8Vfs*8 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs1458356584; called by pindel, varscan2
- PANK2 | c.1052C>T p.S351L (on ENST00000316562 / NM_153638.3; = p.S60L on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1394252871; called by muse, mutect2, varscan2
- PLPP3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64839298; called by muse, mutect2, varscan2
- PWWP2A | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs754247679, COSV61045973; called by muse, mutect2, varscan2
- RTL3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as rs267606516, COSV58185965, COSV58186247; called by muse, mutect2, varscan2
- SERTAD2 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57639984; called by muse, mutect2, varscan2
- SNW1 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV55055717; called by muse, mutect2, varscan2
- SNX13 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 26/226 reads (12%) | catalogued as COSV99073123; called by muse, mutect2, varscan2
- SYNRG | c.2420_2421del p.S807Cfs*22 | Frame Shift Del (DEL) | VAF 58/379 reads (15%) | catalogued as rs1175672487; called by pindel, varscan2
- TAF1L | c.4247G>A p.R1416K | Missense Mutation (SNP) | VAF 61/448 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV54264633; called by muse, mutect2, varscan2
- TCHH | c.5668_5670del p.K1890del | In Frame Del (DEL) | VAF 17/152 reads (11%) | catalogued as rs1245910279; called by mutect2, pindel, varscan2
- TMEM262 | c.109G>A p.V37M (on ENST00000530719 / NM_001282448.1; = p.V35M on NM_001242631.2) | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs1253477070; called by muse, mutect2, varscan2
- TMPRSS3 | c.1309G>C p.V437L | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs114904237; called by muse, mutect2, varscan2
- TPBG | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1201644705; called by muse, mutect2, varscan2
- TRAV6 | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs757446750; called by muse, mutect2, varscan2
- TTN | c.62186C>T p.S20729F (on ENST00000591111; = p.S13305F on NM_003319.4) | Missense Mutation (SNP) | VAF 50/642 reads (8%) | PolyPhen possibly damaging (0.458); catalogued as COSV59934203; called by muse, mutect2
- USP17L2 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 128/806 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs373560534; called by mutect2, varscan2
- USP17L2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 129/834 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.184); catalogued as rs745419434; called by muse, mutect2, varscan2
- ZAP70 | c.1194C>G p.I398M | Missense Mutation (SNP) | VAF 227/373 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53853832, COSV53856051; called by muse, mutect2, varscan2
- ZCCHC14 | c.1013C>T p.S338F (on ENST00000268616; = p.S475F on NM_015144.3) | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51885185; called by muse, mutect2, varscan2
- AIRE | c.792del p.A265Pfs*113 | Frame Shift Del (DEL) | VAF 81/296 reads (27%) | called by mutect2, pindel, varscan2
- AK2 | c.337_339del p.E113del (on ENST00000354858; = p.E155del on NM_001625.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 65/451 reads (14%) | called by pindel, varscan2
- ANKRD31 | c.5380C>T p.Q1794* | Nonsense Mutation (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- ANKRD35 | c.2774A>T p.D925V | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ARL1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ASXL3 | c.1907C>G p.S636* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- CBLL1 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPE | c.1395_1398del p.C466Qfs*13 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by pindel, varscan2
- COL4A2 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CREBBP | c.2910_2911del p.N970Kfs*21 | Frame Shift Del (DEL) | VAF 50/453 reads (11%) | called by mutect2, pindel, varscan2
- CUTC | c.269dup p.L90Ffs*6 | Frame Shift Ins (INS) | VAF 50/298 reads (17%) | called by mutect2, pindel, varscan2
- DAGLB | c.280_281del p.M94Vfs*2 | Frame Shift Del (DEL) | VAF 76/678 reads (11%) | called by mutect2, pindel, varscan2
- DCST2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- DUOX2 | c.1608_1610del p.N537del | In Frame Del (DEL) | VAF 80/566 reads (14%) | called by mutect2, pindel, varscan2
- EFCAB3 | c.648A>C p.E216D | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ERVV-2 | c.735_736dup p.R246Pfs*29 | Frame Shift Ins (INS) | VAF 16/121 reads (13%) | called by mutect2, varscan2
- FREM2 | c.7912G>A p.E2638K | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FREM2 | c.7913A>T p.E2638V | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- IGF2R | c.2724G>A p.W908* | Nonsense Mutation (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- INTS2 | c.3445+1G>A p.X1149_splice | Splice Site (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- MAP2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- MED19 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED26 | c.1262_1263del p.K421Rfs*7 | Frame Shift Del (DEL) | VAF 53/287 reads (18%) | called by mutect2, pindel, varscan2
- METAP1D | c.989A>T p.K330I | Missense Mutation (SNP) | VAF 96/514 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MUC12 | c.9962G>A p.G3321D (on ENST00000379442; = p.G3178D on NM_001164462.1) | Missense Mutation (SNP) | VAF 136/2464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MUC22 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT tolerated (0.22); called by muse, mutect2, varscan2
- MUC22 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT tolerated (0.3); called by muse, mutect2, varscan2
- MYO16 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- NEBL | c.833A>C p.D278A | Missense Mutation (SNP) | VAF 97/418 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NSMCE4A | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- OLIG2 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR10A3 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5T2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCARE | c.3724C>T p.P1242S | Missense Mutation (SNP) | VAF 68/444 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PDXDC1 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PELP1 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- PHTF1 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PIK3C2B | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- PKHD1L1 | c.8453T>G p.L2818R | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, varscan2
- PMPCB | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPTC7 | c.222C>A p.L74= | Splice Region (SNP) | VAF 30/216 reads (14%) | called by muse, mutect2
- PTPRB | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by mutect2, varscan2
- RFXANK | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 100/649 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGPD4 | c.3158G>A p.G1053E | Missense Mutation (SNP) | VAF 309/795 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNPS1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SMURF1 | c.1394dup p.Y465* | Nonsense Mutation (INS) | VAF 35/281 reads (12%) | called by mutect2, pindel, varscan2
- SSTR3 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SUPT7L | c.1130T>A p.I377N | Missense Mutation (SNP) | VAF 116/431 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TMEM225 | c.182-1G>A p.X61_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- TMF1 | c.1675A>G p.M559V | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TPM4 | c.4_19del p.A2Gfs*16 (on ENST00000300933; = p.A28Gfs*59 on NM_003290.3) | Frame Shift Del (DEL) | VAF 55/241 reads (23%) | called by mutect2, pindel, varscan2
- TRGJP1 | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 7/175 reads (4%) | called by muse, mutect2
- TRMU | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 154/521 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UBE2O | c.3415G>A p.V1139M | Missense Mutation (SNP) | VAF 72/519 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- USH1C | c.1286A>T p.D429V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZFP37 | c.658A>T p.R220W | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF385B | c.545A>C p.N182T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF441 | c.1872C>A p.F624L | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF460 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- A4GALT | c.945C>T p.H315= | Silent (SNP) | VAF 98/379 reads (26%) | catalogued as rs1487412478; called by muse, mutect2, varscan2
- ALKBH8 | c.969C>T p.S323= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2
- AP2A2 | c.588C>T p.L196= | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2
- AQR | c.4407A>C p.A1469= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- ARHGAP44 | c.1974C>T p.V658= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1337314471; called by muse, varscan2
- ASXL2 | c.4050A>G p.V1350= | Silent (SNP) | VAF 82/200 reads (41%) | catalogued as COSV55467667; called by muse, mutect2, varscan2
- C8orf82 | c.312C>T p.F104= | Silent (SNP) | VAF 100/343 reads (29%) | catalogued as COSV52772439; called by muse, mutect2, varscan2
- CACNB4 | c.525A>G p.K175= | Silent (SNP) | VAF 81/160 reads (51%) | catalogued as rs942914070; called by muse, mutect2, varscan2
- CAMTA2 | c.780C>T p.T260= | Silent (SNP) | VAF 28/191 reads (15%) | catalogued as rs763557653; called by muse, mutect2, varscan2
- CLEC4G | c.342G>A p.A114= | Silent (SNP) | VAF 78/486 reads (16%) | catalogued as COSV100183592; called by muse, mutect2, varscan2
- EMILIN2 | c.1503G>T p.L501= | Silent (SNP) | VAF 179/305 reads (59%) | called by muse, mutect2, varscan2
- FBN3 | c.2352C>T p.A784= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs200569494; called by muse, mutect2, varscan2
- FBXL7 | c.654A>G p.E218= | Silent (SNP) | VAF 59/536 reads (11%) | called by muse, mutect2, varscan2
- GAD2 | c.639T>C p.F213= | Silent (SNP) | VAF 84/397 reads (21%) | called by muse, mutect2, varscan2
- HIPK2 | c.2169G>C p.L723= | Silent (SNP) | VAF 55/134 reads (41%) | called by muse, mutect2, varscan2
- HSD17B6 | c.270C>T p.I90= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs368361992; called by muse, mutect2, varscan2
- ILK | c.432G>A p.L144= | Silent (SNP) | VAF 49/274 reads (18%) | called by muse, mutect2, varscan2
- KMT5C | c.597C>A p.A199= | Silent (SNP) | VAF 106/266 reads (40%) | called by muse, mutect2, varscan2
- MAPK3 | c.108C>T p.F36= | Silent (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2, varscan2
- MED16 | c.663C>T p.T221= | Silent (SNP) | VAF 70/372 reads (19%) | catalogued as rs114495755; called by muse, mutect2, varscan2
- MLLT10 | c.147C>T p.V49= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as rs1425180622, COSV100308397; called by muse, mutect2, varscan2
- NOA1 | c.390G>A p.P130= | Silent (SNP) | VAF 60/363 reads (17%) | catalogued as rs1466496791; called by muse, mutect2, varscan2
- OTUD7A | c.1983C>T p.I661= (on ENST00000307050 / NM_001382637.1; = p.I654= on NM_130901.3) | Silent (SNP) | VAF 99/290 reads (34%) | called by muse, mutect2, varscan2
- PLCB1 | c.2535A>C p.G845= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2
- PLEC | c.13191C>T p.P4397= (on ENST00000322810 / NM_201380.4; = p.P4287= on NM_000445.5) | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as rs782590185; called by muse, mutect2
- PLEKHH3 | c.2130C>T p.A710= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as rs1345004929; called by muse, mutect2, varscan2
- PTPRS | c.2832G>A p.G944= | Silent (SNP) | VAF 78/429 reads (18%) | called by muse, mutect2, varscan2
- QSOX2 | c.249C>T p.L83= | Silent (SNP) | VAF 201/575 reads (35%) | catalogued as rs1554758417; called by muse, mutect2, varscan2
- RTN4R | c.984G>A p.E328= | Silent (SNP) | VAF 74/238 reads (31%) | catalogued as COSV50381845; called by muse, mutect2, varscan2
- SEPHS2 | c.135C>G p.L45= | Silent (SNP) | VAF 68/407 reads (17%) | called by muse, mutect2, varscan2
- SLC3A1 | c.975G>A p.L325= | Silent (SNP) | VAF 31/242 reads (13%) | catalogued as COSV99576888; called by muse, mutect2, varscan2
- SPINK5 | c.2514A>G p.T838= | Silent (SNP) | VAF 96/273 reads (35%) | catalogued as rs777226517, COSV56258019; called by muse, mutect2, varscan2
- TANC1 | c.2832C>T p.H944= | Silent (SNP) | VAF 80/708 reads (11%) | called by muse, mutect2, varscan2
- UBAP2L | c.663G>T p.T221= | Silent (SNP) | VAF 49/264 reads (19%) | called by muse, mutect2, varscan2
- WWC3 | c.1671G>A p.R557= | Silent (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- ZXDA | c.630G>A p.G210= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs766840565; called by muse, mutect2, varscan2
- AC008080.1 | n.646G>A | RNA (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- BRD2 | c.-753G>A | 5'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- CNBD1 | c.*29_*32del | 3'UTR (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- CNNM3 | c.*328dup | 3'UTR (INS) | VAF 157/337 reads (47%) | called by mutect2, pindel, varscan2
- COL5A3 | c.-37C>G | 5'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1106A>G | RNA (SNP) | VAF 49/488 reads (10%) | called by muse, varscan2
- GYPA | c.232+35C>T | Intron (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- KRT5 | c.832-12_832-11del | Intron (DEL) | VAF 42/385 reads (11%) | called by mutect2, pindel, varscan2
- LINC02413 | n.163C>T | RNA (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- LOXL2 | c.-208T>C | 5'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640140 C>G | 5'Flank (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
- RAI1 | c.-16-14166C>A | Intron (SNP) | VAF 65/444 reads (15%) | called by muse, mutect2, varscan2
- STX17 | c.123+689A>G | Intron (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- TAAR3P | n.984C>T | RNA (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2
- ZFAND4 | c.570-404A>G | Intron (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
